CCDI case PBBULB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/31aeeb50-956c-47ec-8a8a-667ea22f4cfc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 4.8 years (1,764 days).

Biospecimens (3 samples)
- Sample 0DHDZD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHDZO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHE02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
